Gene-level copy-number profile of tumor specimen TCGA-05-5425-01A from TCGA case TCGA-05-5425, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.5 years (25,020 days).
Specimen TCGA-05-5425-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.4855d77f-2710-4807-bda2-f0886db79995.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-5425-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dde526c8-7501-4228-b930-75dda6862d69

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 2,501; copy number 1: 34,801; copy number 2: 19,140; copy number 3: 3,261; copy number 4: 456; copy number 5: 15; copy number 6: 89.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-5425-01A-02D-1624-01): tumor purity 0.71, ploidy 1.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 115 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,098,660–15,544,294, 50 genes: AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P.
- chr9:20,331,446–22,214,672, 65 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,821 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–166,975,540, 934 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr5:25,349,841–44,828,592, 296 genes, copy number 3 (broad region; genes not listed).
- chr6:167,607–11,515,710, 225 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr6:18,522,735–18,674,001, 2 genes, copy number 3: MIR548A1HG, MIR548A1.
- chr6:63,440,766–65,707,226, 17 genes, copy number 3: AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr7:53,316,149–63,154,934, 175 genes, copy number 3 (broad region; genes not listed).
- chr7:83,355,154–85,636,344, 18 genes, copy number 3: AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1.
- chr7:86,782,357–92,917,187, 88 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr8:36,764,445–37,069,418, 6 genes, copy number 3: RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1.
- chr11:59,511,368–61,607,550, 91 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr11:66,347,950–67,425,607, 59 genes, copy number 3 (within-gene range 1–3): AP001107.9, SLC29A2, Metazoa_SRP, BRD9P1, RNU1-84P, AP001107.5, NPAS4, AP002748.1, MRPL11, AP002748.3, PELI3, AP002748.4, DPP3, AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF, CCDC87, CCS, RNU4-39P, RBM14, RBM14-RBM4, RBM4, RBM4B, SPTBN2, RN7SL12P, C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86, SYT12, MIR6860, RHOD, KDM2A, AP001885.1, AP001885.3, GRK2, ANKRD13D, SSH3, AP001885.2, RAD9A, POLD4, AP003419.1, AP003419.2, RN7SKP239, CLCF1, AP003419.3, RNU6-1238P, PPP1CA, TBC1D10C, CARNS1.
- chr11:82,603,529–83,423,516, 31 genes, copy number 3: AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:83,643,602–83,815,263, 3 genes, copy number 3: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr11:87,565,994–90,915,052, 89 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr11:91,114,724–91,383,289, 6 genes, copy number 5: OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1.
- chr11:100,336,856–102,843,609, 44 genes, copy number 3–5: RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3.
- chr12:26,318,953–26,833,194, 2 genes, copy number 3 (within-gene range 1–3): AC024145.1, ITPR2.
- chr12:26,373,598–42,024,329, 216 genes, copy number 3 (broad region; genes not listed).
- chr12:54,497,752–55,427,192, 34 genes, copy number 3 (within-gene range 2–3): NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1, VDAC1P5, MUCL1, TESPA1, AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76.
- chr12:55,444,069–55,493,316, 3 genes, copy number 3: OR6C2, OR6C70, OR6C68.
- chr13:98,142,562–99,086,625, 20 genes, copy number 3 (within-gene range 1–3): FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1, FARP1-AS1, STK24, AL356423.1, STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1, DOCK9, DOCK9-AS1, AL161420.1, RPL7L1P12, RNU6-83P.
- chr14:18,333,726–19,936,757, 82 genes, copy number 3 (broad region; genes not listed).
- chr18:20,946,906–23,956,222, 63 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr19:27,638,483–32,405,560, 89 genes, copy number 3–4 (broad region; genes not listed).
- chr19:34,254,552–37,906,677, 207 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr19:37,963,853–37,964,790, 1 gene, copy number 3: AC008395.1.
- chr19:41,350,853–41,425,001, 2 genes, copy number 3 (within-gene range 2–3): AC011462.1, TMEM91.
- chr19:41,373,971–44,821,421, 178 genes, copy number 3 (broad region; genes not listed).
- chr20:87,250–23,190,419, 446 genes, copy number 4 (broad region; genes not listed).
- chr20:24,445,391–32,608,893, 149 genes, copy number 3 (broad region; genes not listed).
- chr20:33,217,310–38,383,179, 169 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr20:51,386,957–56,786,087, 76 genes, copy number 3 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 34,246. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
